National Lung Screening Trial (NLST) participant 129117 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 18): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 50 mA, display field of view 30 cm, reconstruction filter GE Standard.
- T1 (day 347): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 50 mA, display field of view 29 cm, reconstruction filter GE Standard.
- T2 (day 732): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 50 mA, display field of view 32 cm, reconstruction filter GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (1 abnormality; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,427.
